CCDI case PBCDIB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3a64f930-38c4-44b6-a527-29db0fb9e3da

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 10.9 years (3,995 days).

Biospecimens (3 samples)
- Sample 0DP7LB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP7LL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DP7LM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
